Somatic mutation profile of tumor specimen MBCProject_0763_T1_WES (aliquot MBCProject_0763_T1_WES_1) from CMI case MBCProject_0763, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 54.8 years (20,006 days).
Specimen MBCProject_0763_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1754a71-88f2-4bde-b9d9-e70d54fca9ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_0763_SALIVA (Saliva), aliquot MBCProject_0763_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7d5dbd79-462d-4ae0-9a4e-b17f2602d280

The open-access MAF lists 53 somatic variants for this specimen: 30 protein-altering or splice-affecting, 14 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 14, Intron 5, 3'UTR 2, 5'Flank 1, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 41/245 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AGO4 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.545); catalogued as COSV64617053; called by muse, mutect2
- FAAP100 | c.1435C>T p.R479W | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs372212736; called by muse, mutect2
- FETUB | c.449C>T p.T150M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs541290079, COSV54006855; called by muse, mutect2, varscan2
- FUBP3 | c.1511G>A p.S504N | Missense Mutation (SNP) | VAF 36/127 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as rs746456608; called by muse, mutect2, varscan2
- GPR15 | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 22/147 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752760213, COSV52520641, COSV52521171, COSV99423711; called by muse, mutect2, varscan2
- IL17REL | c.88C>T p.R30C | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.458); catalogued as rs746680155; called by muse, mutect2, varscan2
- MFN2 | c.205G>C p.V69L | Missense Mutation (SNP) | VAF 28/330 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as CM041389; called by muse, mutect2
- MRPS2 | c.521G>A p.G174D | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs866858922; called by muse, mutect2, varscan2
- PLAAT4 | c.485C>T p.A162V | Missense Mutation (SNP) | VAF 42/137 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs35845275; called by muse, mutect2, varscan2
- TNNI3K | c.1922G>A p.R641Q | Missense Mutation (SNP) | VAF 29/115 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.167); catalogued as rs200171980, COSV58546021, COSV58558883; called by muse, mutect2, varscan2
- TRIM51 | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 19/108 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as rs1459339906, COSV55266403; called by muse, mutect2, varscan2
- ZNF572 | c.1076C>T p.S359F | Missense Mutation (SNP) | VAF 30/229 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV60001143, COSV60002420; called by muse, mutect2, varscan2
- ANK2 | c.5908G>A p.E1970K | Missense Mutation (SNP) | VAF 8/188 reads (4%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.021); called by muse, mutect2
- ANO9 | c.1526C>T p.S509F | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.089); called by muse, varscan2
- ATP6V1G1 | c.104A>G p.Q35R | Missense Mutation (SNP) | VAF 19/178 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- BRINP1 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.245); called by muse, mutect2, varscan2
- CPNE8 | c.95G>T p.C32F | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FER1L5 | c.5876A>C p.E1959A (on ENST00000623019; = p.E1923A on NM_001293083.2) | Missense Mutation (SNP) | VAF 17/141 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- GPS2 | c.310del p.E104Nfs*5 | Frame Shift Del (DEL) | VAF 25/84 reads (30%) | called by mutect2, pindel, varscan2
- IARS2 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 9/187 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); called by muse, mutect2
- MUC6 | c.6266C>T p.S2089F | Missense Mutation (SNP) | VAF 37/214 reads (17%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- ODF3B | c.434C>A p.T145K | Missense Mutation (SNP) | VAF 9/220 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.01); called by muse, mutect2
- OR5H2 | c.178C>T p.L60F | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- PCF11 | c.3484C>G p.P1162A | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- PTCD2 | c.366C>A p.N122K | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RNASE7 | c.360G>T p.R120S | Missense Mutation (SNP) | VAF 13/202 reads (6%) | SIFT tolerated (0.1); PolyPhen benign (0.246); called by muse, mutect2
- SDK2 | c.5637G>C p.E1879D | Missense Mutation (SNP) | VAF 18/149 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TUBA3D | c.1282C>G p.L428V | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VLDLR | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 24/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ANO9 | c.1869C>T p.F623= | Silent (SNP) | VAF 11/135 reads (8%) | catalogued as rs373573370; called by muse, mutect2
- BDP1 | c.1836G>A p.L612= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2
- CELSR1 | c.4269C>T p.I1423= | Silent (SNP) | VAF 20/194 reads (10%) | catalogued as rs376155844; called by muse, mutect2
- CPNE9 | c.1282C>T p.L428= | Silent (SNP) | VAF 15/90 reads (17%) | called by muse, mutect2, varscan2
- DARS2 | c.597A>G p.E199= | Silent (SNP) | VAF 13/354 reads (4%) | called by muse, mutect2
- DNAH1 | c.6597C>T p.I2199= | Silent (SNP) | VAF 18/157 reads (11%) | called by muse, mutect2, varscan2
- EMX1 | c.165C>A p.T55= | Silent (SNP) | VAF 7/51 reads (14%) | called by muse, mutect2, varscan2
- HJV | c.1254C>T p.L418= (on ENST00000336751 / NM_213653.4; = p.L305= on NM_145277.5) | Silent (SNP) | VAF 33/185 reads (18%) | called by muse, mutect2, varscan2
- MPV17 | c.60C>T p.V20= | Silent (SNP) | VAF 16/318 reads (5%) | called by muse, mutect2
- NCAPH2 | c.1737C>T p.T579= | Silent (SNP) | VAF 10/106 reads (9%) | called by muse, mutect2, varscan2
- SERINC4 | c.984G>C p.L328= | Silent (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- TOP2B | c.1332G>A p.L444= (on ENST00000264331 / NM_001330700.2; = p.L439= on NM_001068.3) | Silent (SNP) | VAF 25/163 reads (15%) | called by muse, mutect2, varscan2
- TUBA3D | c.156C>T p.F52= | Silent (SNP) | VAF 10/162 reads (6%) | called by muse, mutect2
- TYW3 | c.159C>T p.I53= | Silent (SNP) | VAF 11/113 reads (10%) | called by muse, mutect2, varscan2
- AK2 | c.*437T>G | 3'UTR (SNP) | VAF 6/65 reads (9%) | called by muse, mutect2
- FNIP2 | c.655+150C>G | Intron (SNP) | VAF 13/166 reads (8%) | called by muse, mutect2
- JPT2 | c.*199G>T | 3'UTR (SNP) | VAF 21/402 reads (5%) | called by muse, mutect2
- PDE1C | c.980+18G>C | Intron (SNP) | VAF 14/294 reads (5%) | called by muse, mutect2
- PPRC1 | c.4551-10C>T | Intron (SNP) | VAF 14/140 reads (10%) | called by muse, mutect2
- RGS13 | c.66-10C>G | Intron (SNP) | VAF 10/154 reads (6%) | called by muse, mutect2
- SHISA5 | c.315-3657C>T | Intron (SNP) | VAF 13/75 reads (17%) | called by muse, mutect2, varscan2
- TMEM183B | n.629T>C | RNA (SNP) | VAF 21/215 reads (10%) | catalogued as rs370745218; called by muse, mutect2, varscan2
- ZNF687 | chr1:151281551 C>T | 5'Flank (SNP) | VAF 18/347 reads (5%) | catalogued as rs1274950416; called by muse, mutect2
